Gene-level copy-number profile of tumor specimen RC-B6VL-TBP1-A from RC case RC-B6VL, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,074 days).
Specimen RC-B6VL-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file afb9b46b-2f96-4391-a6d0-0090ed411566.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6VL-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/b21d6b28-ddf3-4bd0-b96e-9254abb50765

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 209; copy number 1: 4,459; copy number 2: 51,876; copy number 3: 2,365.

Homozygous deletions (total copy number 0; autosomes only): 205 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:142,286,917–142,317,546, 2 genes (within-gene range 0–2): RPL5P13, LSM3P4.
- chr7:38,239,580–38,340,998, 15 genes (within-gene range 0–2): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV7, TRGV6.
- chr7:142,308,542–142,802,748, 80 genes (broad region; genes not listed).
- chr14:21,950,406–22,552,156, 108 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
